Somatic mutation profile of cancer-model specimen HCM-CSHL-0060-C18-85A (3D Organoid; aliquot HCM-CSHL-0060-C18-85A-01D-A77E-36), derived from the primary tumor of HCMI case HCM-CSHL-0060-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 50.8 years (18,571 days).
Specimen HCM-CSHL-0060-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb6484b3-6e5b-4ce4-9cce-521337db4131.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0060-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0060-C18-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8acfae1-bfa2-4694-8949-a8601bb218ec

The open-access MAF lists 100 somatic variants for this specimen: 66 protein-altering or splice-affecting, 26 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 26, Intron 4, Splice Region 3, Nonsense Mutation 3, 5'Flank 2, Frame Shift Ins 2, In Frame Del 2, Frame Shift Del 2, RNA 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 409/409 reads (100%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACACB | c.6205G>A p.G2069S | Missense Mutation (SNP) | VAF 132/200 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as rs201323153; called by muse, mutect2, varscan2
- AMER1 | c.1756C>T p.R586* | Nonsense Mutation (SNP) | VAF 178/179 reads (99%) | catalogued as COSV57666208; called by muse, mutect2, varscan2
- ANO1 | c.985G>A p.G329S | Missense Mutation (SNP) | VAF 102/155 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as rs772929785; called by muse, mutect2, varscan2
- ANTXRL | c.1579C>T p.R527C | Missense Mutation (SNP) | VAF 160/608 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.272); catalogued as rs1253811462; called by muse, mutect2, varscan2
- AP3D1 | c.3164+1G>A p.X1055_splice | Splice Site (SNP) | VAF 92/342 reads (27%) | catalogued as COSV61426394; called by muse, mutect2, varscan2
- APC | c.4508del p.S1503Yfs*4 | Frame Shift Del (DEL) | VAF 55/75 reads (73%) | catalogued as CM000126, COSV57332733, COSV57338787; called by mutect2, pindel, varscan2
- CHID1 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 95/288 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs139154177; called by muse, mutect2, varscan2
- CHRM5 | c.1244C>T p.T415M | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.214); catalogued as rs193093417, COSV67248269; called by muse, mutect2, varscan2
- DST | c.15941C>T p.T5314M (on ENST00000361203 / NM_001374722.1; = p.T2902M on NM_015548.5) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.967); catalogued as rs756527130, COSV55014242, COSV55029896; called by muse, mutect2, varscan2
- FANCM | c.351G>C p.K117N | Missense Mutation (SNP) | VAF 167/354 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771052141; called by muse, mutect2, varscan2
- FATE1 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 74/173 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs369789283; called by muse, mutect2, varscan2
- FTCD | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 150/338 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as rs373471933; called by muse, mutect2, varscan2
- GDF2 | c.1207G>A p.V403I | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs367957332; called by muse, mutect2, varscan2
- GRID1 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 76/162 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as rs148165863; called by muse, mutect2, varscan2
- GRIK3 | c.2543G>A p.R848H | Missense Mutation (SNP) | VAF 169/322 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs746478247, COSV66135600, COSV66143041; called by muse, mutect2, varscan2
- LCE3D | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 147/625 reads (24%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs775921101, COSV64230771; called by muse, mutect2, varscan2
- LONRF2 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 62/91 reads (68%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.944); catalogued as rs772166966, COSV66539320; called by muse, mutect2, varscan2
- MAPKBP1 | c.1748G>A p.R583H (on ENST00000456763 / NM_001128608.2; = p.R577H on NM_014994.3) | Missense Mutation (SNP) | VAF 48/255 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as rs773163952; called by muse, mutect2, varscan2
- MED12 | c.4070G>A p.R1357H | Missense Mutation (SNP) | VAF 272/272 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61332408, COSV61353101; called by muse, mutect2, varscan2
- MOG | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 133/265 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757305712; called by muse, mutect2, varscan2
- OLFML2B | c.754G>A p.V252M | Missense Mutation (SNP) | VAF 138/264 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.62); catalogued as rs750492409, COSV54198425; called by muse, mutect2, varscan2
- OR11L1 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 206/545 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs759005461; called by muse, mutect2
- OR2L2 | c.849G>T p.M283I | Missense Mutation (SNP) | VAF 90/198 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs373354734, COSV63547472; called by muse, mutect2, varscan2
- OR4K15 | c.908C>T p.T303M (on ENST00000305051; = p.T279M on NM_001005486.1) | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs150969455, COSV59301119; called by muse, mutect2, varscan2
- PCDHB8 | c.1082C>A p.A361E | Missense Mutation (SNP) | VAF 181/689 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.279); catalogued as COSV50754565; called by muse, mutect2, varscan2
- POPDC3 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 62/141 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.678); catalogued as rs111547826, COSV54643244; called by muse, mutect2, varscan2
- RGPD4 | c.3344C>T p.T1115M | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758889509; called by muse, mutect2, varscan2
- SAGE1 | c.1796C>T p.S599L | Missense Mutation (SNP) | VAF 96/96 reads (100%) | SIFT tolerated (0.35); PolyPhen benign (0.41); catalogued as rs781798413, COSV61012362; called by muse, mutect2, varscan2
- SLC26A3 | c.2255G>A p.R752H | Missense Mutation (SNP) | VAF 132/133 reads (99%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as rs765288477, COSV60641616; called by muse, mutect2, varscan2
- SYNE1 | c.3584C>A p.S1195Y (on ENST00000367255 / NM_182961.4; = p.S1202Y on NM_033071.3) | Missense Mutation (SNP) | VAF 157/304 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV54928469; called by muse, mutect2, varscan2
- TMEM94 | c.4003C>T p.R1335* | Nonsense Mutation (SNP) | VAF 45/183 reads (25%) | catalogued as rs565769905, COSV58601308; called by muse, mutect2, varscan2
- TRAPPC11 | c.1279_1281del p.V427del | In Frame Del (DEL) | VAF 58/74 reads (78%) | catalogued as rs779028056; called by pindel, varscan2
- TRPV6 | c.2047C>T p.R683W | Missense Mutation (SNP) | VAF 54/54 reads (100%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs775632242, COSV63890810; called by muse, mutect2, varscan2
- TTC28 | c.4351G>A p.G1451S | Missense Mutation (SNP) | VAF 77/78 reads (99%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs767044155; called by muse, mutect2, varscan2
- WBP2 | c.657C>T p.A219= | Splice Region (SNP) | VAF 213/213 reads (100%) | catalogued as rs370952739; called by muse, mutect2, varscan2
- ZNF217 | c.1460A>G p.N487S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as rs757386385; called by muse, mutect2, varscan2
- ZNF628 | c.2212G>A p.A738T | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as rs747922811, COSV52697724; called by muse, mutect2, varscan2
- ZNF789 | c.389A>G p.H130R | Missense Mutation (SNP) | VAF 107/155 reads (69%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs369068130; called by muse, mutect2, varscan2
- AADAT | c.853_870del p.I285_V290del | In Frame Del (DEL) | VAF 26/33 reads (79%) | called by mutect2, pindel, varscan2
- AAR2 | c.1155T>A p.N385K | Missense Mutation (SNP) | VAF 67/348 reads (19%) | PolyPhen benign (0.403); called by muse, mutect2, varscan2
- ADAM12 | c.2670-1G>A p.X890_splice | Splice Site (SNP) | VAF 63/149 reads (42%) | called by muse, mutect2, varscan2
- AMFR | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 165/233 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ARHGAP33 | c.2422T>A p.Y808N | Missense Mutation (SNP) | VAF 24/402 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); called by muse, mutect2
- BRMS1L | c.414A>C p.E138D | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC102B | c.1190A>G p.K397R | Missense Mutation (SNP) | VAF 35/36 reads (97%) | SIFT tolerated (0.29); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CSMD2 | c.2971A>G p.R991G | Missense Mutation (SNP) | VAF 114/538 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- DYNC2H1 | c.6944C>A p.T2315K | Missense Mutation (SNP) | VAF 178/248 reads (72%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- EMILIN2 | c.2690C>T p.S897F | Missense Mutation (SNP) | VAF 70/161 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- GABRG2 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 113/114 reads (99%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HS3ST3B1 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 96/242 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNJ3 | c.943T>G p.S315A | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KISS1 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 219/493 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- KNDC1 | c.1444T>C p.Y482H | Missense Mutation (SNP) | VAF 188/390 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.031); called by muse, varscan2
- LMAN2L | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 112/191 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MASTL | c.685C>A p.Q229K | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC5AC | c.221del p.P74Rfs*60 | Frame Shift Del (DEL) | VAF 52/161 reads (32%) | called by mutect2, pindel, varscan2
- PI4KA | c.3246A>G p.E1082= | Splice Region (SNP) | VAF 76/76 reads (100%) | called by muse, mutect2, varscan2
- PIK3CB | c.478dup p.I160Nfs*22 | Frame Shift Ins (INS) | VAF 34/160 reads (21%) | called by mutect2, pindel, varscan2
- RNF31 | c.2024dup p.L675Ffs*44 | Frame Shift Ins (INS) | VAF 70/159 reads (44%) | called by mutect2, pindel, varscan2
- SMG5 | c.633T>A p.I211= | Splice Region (SNP) | VAF 44/250 reads (18%) | called by muse, mutect2, varscan2
- SYNE1 | c.14579C>A p.S4860Y (on ENST00000367255 / NM_182961.4; = p.S4789Y on NM_033071.3) | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- TENT4B | c.877C>T p.R293W (on ENST00000561678 / NM_001365323.2; = p.R278W on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/270 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- TRDN | c.400G>C p.D134H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TRIM64B | c.201T>G p.N67K | Missense Mutation (SNP) | VAF 236/1430 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UPF1 | c.2477C>A p.T826N (on ENST00000599848 / NM_001297549.2; = p.T815N on NM_002911.4) | Missense Mutation (SNP) | VAF 56/255 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACACA | c.3813C>T p.G1271= | Silent (SNP) | VAF 91/298 reads (31%) | catalogued as rs761999661; called by muse, mutect2, varscan2
- BTAF1 | c.267A>G p.E89= | Silent (SNP) | VAF 50/108 reads (46%) | called by muse, varscan2
- CAPN15 | c.1923G>A p.A641= | Silent (SNP) | VAF 157/350 reads (45%) | catalogued as rs202164006; called by muse, mutect2, varscan2
- CD1A | c.264T>C p.R88= | Silent (SNP) | VAF 85/320 reads (27%) | called by muse, mutect2, varscan2
- CFAP43 | c.2127C>A p.V709= | Silent (SNP) | VAF 66/132 reads (50%) | called by muse, varscan2
- CHIC1 | c.90G>A p.S30= | Silent (SNP) | VAF 115/116 reads (99%) | called by mutect2, varscan2
- CNTROB | c.2676G>A p.P892= | Silent (SNP) | VAF 27/188 reads (14%) | catalogued as rs572722264, COSV100972613, COSV66609146; called by muse, mutect2, varscan2
- CRACD | c.591C>T p.N197= | Silent (SNP) | VAF 117/117 reads (100%) | catalogued as rs763430050; called by muse, mutect2, varscan2
- CTNNA2 | c.2247C>T p.A749= | Silent (SNP) | VAF 79/146 reads (54%) | catalogued as rs745517637, COSV100562552; called by muse, mutect2, varscan2
- DSTYK | c.1728C>T p.L576= | Silent (SNP) | VAF 84/420 reads (20%) | called by muse, mutect2, varscan2
- GHSR | c.732C>T p.R244= | Silent (SNP) | VAF 79/315 reads (25%) | called by muse, mutect2, varscan2
- HSPA5 | c.1185G>A p.A395= | Silent (SNP) | VAF 121/121 reads (100%) | catalogued as rs775362964; called by muse, mutect2, varscan2
- IL17RA | c.1572G>A p.P524= | Silent (SNP) | VAF 116/274 reads (42%) | catalogued as COSV60051119; called by muse, mutect2, varscan2
- JPH1 | c.1521G>A p.T507= | Silent (SNP) | VAF 201/443 reads (45%) | catalogued as rs773323471, COSV100646573; called by muse, mutect2, varscan2
- MMP2 | c.456C>T p.S152= | Silent (SNP) | VAF 97/302 reads (32%) | catalogued as rs371188032; called by muse, mutect2, varscan2
- MRPL14 | c.45C>T p.S15= | Silent (SNP) | VAF 49/262 reads (19%) | called by muse, mutect2, varscan2
- NMUR1 | c.1059C>T p.P353= | Silent (SNP) | VAF 138/416 reads (33%) | catalogued as rs766587624, COSV59403651, COSV59404268; called by muse, mutect2, varscan2
- PCDHGA12 | c.2391G>A p.S797= | Silent (SNP) | VAF 50/123 reads (41%) | called by muse, mutect2, varscan2
- PDCD7 | c.1354C>T p.L452= | Silent (SNP) | VAF 21/60 reads (35%) | called by muse, mutect2, varscan2
- PEX13 | c.984G>A p.A328= | Silent (SNP) | VAF 121/205 reads (59%) | catalogued as rs144086063; called by muse, mutect2, varscan2
- RYR2 | c.4863T>C p.C1621= | Silent (SNP) | VAF 139/265 reads (52%) | called by muse, mutect2, varscan2
- SNED1 | c.3051G>A p.T1017= | Silent (SNP) | VAF 100/135 reads (74%) | catalogued as rs778911371; called by muse, mutect2, varscan2
- VPS35 | c.2166A>G p.E722= | Silent (SNP) | VAF 81/131 reads (62%) | called by muse, mutect2, varscan2
- ZFHX4 | c.7671T>C p.T2557= | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as COSV51500046; called by muse, mutect2, varscan2
- ZIC1 | c.771C>T p.T257= | Silent (SNP) | VAF 51/300 reads (17%) | called by muse, mutect2, varscan2
- ZNF358 | c.1101C>T p.H367= | Silent (SNP) | VAF 125/468 reads (27%) | catalogued as rs61742929; called by muse, mutect2, varscan2
- AC005008.1 | chr7:81189966 T>C | 5'Flank (SNP) | VAF 39/39 reads (100%) | called by muse, mutect2, varscan2
- FAM183BP | n.918C>T | RNA (SNP) | VAF 66/275 reads (24%) | catalogued as rs758258582; called by muse, mutect2, varscan2
- LINC01553 | n.1191dup | RNA (INS) | VAF 45/99 reads (45%) | called by mutect2, varscan2
- SHCBP1L | chr1:182953182 C>T | 5'Flank (SNP) | VAF 236/439 reads (54%) | called by muse, mutect2, varscan2
- SLC14A1 | c.-22+2286G>A | Intron (SNP) | VAF 132/133 reads (99%) | called by muse, mutect2, varscan2
- TRAPPC12 | c.1604-38A>C | Intron (SNP) | VAF 137/238 reads (58%) | called by muse, mutect2, varscan2
- ZBTB16 | c.1453+62A>G | Intron (SNP) | VAF 64/231 reads (28%) | called by muse, mutect2, varscan2
- ZNF433 | c.4-3738G>A | Intron (SNP) | VAF 81/149 reads (54%) | called by muse, mutect2, varscan2
